Somatic mutation profile of tumor specimen HCM-STAN-1109-D13-01A (aliquot HCM-STAN-1109-D13-01A-04D-A937-36) from HCMI case HCM-STAN-1109-D13, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage 0.
Specimen HCM-STAN-1109-D13-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1339afb-5f24-4781-8e76-0bc32b0daa3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-1109-D13-11A (Solid Tissue Normal), aliquot HCM-STAN-1109-D13-11A-04D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/699778ea-1e12-465f-87a7-eb265fd127f7

The open-access MAF lists 70 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 14, Frame Shift Del 2, Intron 2, 5'Flank 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 50/336 reads (15%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- AGL | c.2690C>G p.S897C | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1166549253; called by muse, mutect2, varscan2
- AKAP6 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 69/463 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1248907673; called by muse, mutect2, varscan2
- BMPR1A | c.1394C>G p.P465R | Missense Mutation (SNP) | VAF 70/453 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64408953; called by muse, mutect2, varscan2
- COL5A1 | c.2725C>T p.R909W | Missense Mutation (SNP) | VAF 57/469 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1257715072, COSV100880665; called by muse, varscan2
- CYP4F12 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 44/524 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs757430082, COSV61173217; called by muse, mutect2
- DDX21 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 64/546 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100826509; called by muse, mutect2, varscan2
- EPHA3 | c.2744C>A p.T915K | Missense Mutation (SNP) | VAF 70/622 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100342795; called by mutect2, varscan2
- FBLN5 | c.433A>T p.I145F | Missense Mutation (SNP) | VAF 73/516 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV50905230, COSV50907908; called by muse, mutect2, varscan2
- FBRSL1 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 65/440 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs371082354; called by muse, mutect2, varscan2
- GRXCR1 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 70/535 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV67671586; called by muse, mutect2, varscan2
- HGF | c.1627G>T p.D543Y | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as rs769438908, COSV55945427, COSV55957122; ClinVar: likely benign; called by muse, mutect2, varscan2
- IHH | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 105/543 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767980207; called by muse, mutect2, varscan2
- ITIH2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 33/383 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as rs267602582, COSV64432176; called by muse, mutect2
- MUC16 | c.40471C>T p.R13491W | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.996); catalogued as rs541610415, COSV66689793, COSV66695495; called by muse, varscan2
- MUC19 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 56/660 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as COSV70102214; called by muse, mutect2
- NAV3 | c.4492C>T p.R1498C | Missense Mutation (SNP) | VAF 56/565 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770042276; called by muse, mutect2, varscan2
- NETO2 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 53/480 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV57451398; called by muse, mutect2, varscan2
- NRXN1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 63/492 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as rs1166363453, COSV68014859; called by muse, mutect2, varscan2
- OR5D18 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 66/716 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as rs761012413; called by muse, mutect2
- OSTN | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs1466087137, COSV100174256; called by muse, mutect2, varscan2
- PCDHGA4 | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 54/614 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as rs747114366, COSV53901792; called by muse, mutect2
- SETBP1 | c.2825G>A p.R942Q | Missense Mutation (SNP) | VAF 100/647 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs763904676, COSV56333397, COSV56338146; called by muse, mutect2, varscan2
- SLC17A7 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 53/372 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1360805794; called by muse, mutect2, varscan2
- SPTBN2 | c.5635G>A p.G1879S | Missense Mutation (SNP) | VAF 67/398 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.153); catalogued as rs1016461653; called by muse, mutect2, varscan2
- TBC1D9B | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 84/619 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs774335841; called by muse, mutect2, varscan2
- TNFSF9 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs1235474474, COSV55538662; called by muse, varscan2
- TPTE | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 54/796 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs759630343; called by muse, mutect2
- TULP4 | c.3494G>A p.R1165Q | Missense Mutation (SNP) | VAF 58/640 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs144691972, COSV100893662; called by muse, mutect2
- ZNF217 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 53/342 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs369074794; called by muse, mutect2, varscan2
- AKNA | c.2495A>G p.E832G | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- ALX4 | c.176A>C p.D59A | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); called by muse, varscan2
- APLNR | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ARHGAP20 | c.1085T>A p.L362H | Missense Mutation (SNP) | VAF 77/683 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP23 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 70/509 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- B3GALT6 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.148); called by muse, varscan2
- FBXW2 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- FTMT | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 63/423 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- HLA-A | c.836_846del p.Q279Lfs*6 | Frame Shift Del (DEL) | VAF 16/168 reads (10%) | called by mutect2, varscan2
- KIAA0232 | c.1579A>G p.M527V | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6F1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 67/524 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2204del p.E735Gfs*2 (on ENST00000259318 / NM_001136562.3; = p.E966Gfs*2 on NM_007203.5) | Frame Shift Del (DEL) | VAF 52/464 reads (11%) | called by mutect2, varscan2
- PCDH17 | c.803C>G p.T268S | Missense Mutation (SNP) | VAF 82/464 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.669); called by muse, mutect2
- PKP4 | c.95C>A p.T32N | Missense Mutation (SNP) | VAF 72/660 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- POTEI | c.2294T>A p.L765Q | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCRT1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPOCK3 | c.1265A>T p.E422V | Missense Mutation (SNP) | VAF 59/430 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- TAAR2 | c.1033T>A p.C345S (on ENST00000367931 / NM_001033080.1; = p.C300S on NM_014626.3) | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMPRSS11F | c.994T>C p.F332L | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRAF2 | c.337A>C p.T113P | Missense Mutation (SNP) | VAF 74/485 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRPM4 | c.2681T>C p.V894A | Missense Mutation (SNP) | VAF 62/511 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, varscan2
- TSPAN19 | c.564T>A p.C188* | Nonsense Mutation (SNP) | VAF 30/362 reads (8%) | called by muse, mutect2
- ZNF517 | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 49/391 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AC113554.1 | c.2205A>G p.P735= | Silent (SNP) | VAF 46/488 reads (9%) | called by muse, mutect2
- CRAT | c.1704C>T p.P568= | Silent (SNP) | VAF 41/262 reads (16%) | catalogued as rs145730542; called by muse, varscan2
- DDHD1 | c.618A>T p.S206= (on ENST00000323669; = p.S403= on NM_030637.3) | Silent (SNP) | VAF 57/431 reads (13%) | called by muse, mutect2, varscan2
- GPN2 | c.39G>A p.A13= | Silent (SNP) | VAF 59/413 reads (14%) | catalogued as rs1339271465; called by muse, mutect2, varscan2
- MAN2A1 | c.1017A>G p.G339= | Silent (SNP) | VAF 12/332 reads (4%) | called by muse, mutect2
- MUC16 | c.27804A>C p.S9268= | Silent (SNP) | VAF 46/394 reads (12%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.375G>T p.R125= | Silent (SNP) | VAF 58/331 reads (18%) | called by muse, varscan2
- PXDNL | c.3753G>A p.A1251= | Silent (SNP) | VAF 79/609 reads (13%) | catalogued as rs762577648; called by muse, mutect2, varscan2
- RPL3 | c.297C>T p.L99= | Silent (SNP) | VAF 74/694 reads (11%) | called by muse, mutect2, varscan2
- SIM2 | c.1824G>C p.R608= | Silent (SNP) | VAF 27/195 reads (14%) | catalogued as rs1478136233; called by muse, varscan2
- SLC26A6 | c.1740C>A p.L580= | Silent (SNP) | VAF 69/469 reads (15%) | catalogued as COSV56571306; called by muse, mutect2, varscan2
- STOX2 | c.2340C>T p.D780= | Silent (SNP) | VAF 56/428 reads (13%) | catalogued as rs369886997, COSV57857904; called by muse, mutect2, varscan2
- TENM3 | c.4308A>T p.G1436= | Silent (SNP) | VAF 46/416 reads (11%) | called by muse, mutect2, varscan2
- TEX13C | c.180C>T p.P60= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as rs866594531; called by mutect2, varscan2
- KCNQ1 | c.1393+26636G>C | Intron (SNP) | VAF 22/209 reads (11%) | called by muse, mutect2, varscan2
- MIR4458 | chr5:8460002 A>T | 5'Flank (SNP) | VAF 50/406 reads (12%) | called by muse, varscan2
- ZNF415 | c.136+24G>C | Intron (SNP) | VAF 42/416 reads (10%) | called by muse, mutect2, varscan2
